Somatic mutation profile of tumor specimen TCGA-06-2558-01A (aliquot TCGA-06-2558-01A-01W-0837-08) from TCGA case TCGA-06-2558, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.3 years (27,511 days).
Specimen TCGA-06-2558-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecdbc1eb-3bf5-4a4e-81ee-b50a9264ea11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2558-10A (Blood Derived Normal), aliquot TCGA-06-2558-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd9365e1-55cb-455e-a23b-7cbabb9e1e52

The open-access MAF lists 107 somatic variants for this specimen: 81 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 64, Silent 26, Nonsense Mutation 8, Frame Shift Ins 8, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 151/233 reads (65%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 100/153 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.750A>T p.E250D | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.845); catalogued as COSV50957674; called by muse, mutect2, varscan2
- ABCC5 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs376038853; called by muse, mutect2, varscan2
- ACP6 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.107); catalogued as rs782391965, COSV65076241; called by muse, mutect2, varscan2
- ACSM2B | c.1676A>G p.Q559R | Missense Mutation (SNP) | VAF 223/1122 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV61656906; called by muse, mutect2, varscan2
- ACSM4 | c.1289G>C p.C430S | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV68066840; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58441385, COSV58441585; called by muse, mutect2
- APC | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs199562537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP10 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs775690026, COSV61474501; called by muse, mutect2, varscan2
- ATP7A | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58443642; called by muse, mutect2
- BRIX1 | c.703C>G p.R235G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57759330, COSV57760667; called by muse, mutect2, varscan2
- CACNA2D1 | c.1478C>G p.S493C | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62373564; called by muse, mutect2, varscan2
- CD101 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs529866838, COSV56716276; called by muse, mutect2, varscan2
- CD163 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs752858863, COSV63129802; called by muse, mutect2, varscan2
- CDKN1A | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV55187185; called by muse, mutect2, varscan2
- CHSY3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777729488, COSV59272015; called by muse, mutect2, varscan2
- CLDN25 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 40/586 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV71620412; called by muse, mutect2
- CLNK | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 325/671 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV57011224; called by muse, mutect2, varscan2
- CORIN | c.2485G>T p.G829C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56686992; called by muse, mutect2, varscan2
- DDX11 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1046226646, COSV52511760; called by muse, mutect2, varscan2
- DNAH17 | c.13346C>T p.A4449V | Missense Mutation (SNP) | VAF 128/263 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143246806, COSV53143544; called by muse, mutect2, varscan2
- ENPEP | c.2000G>T p.R667I | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV54447366; called by muse, mutect2, varscan2
- FADS3 | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV53877446; called by muse, mutect2, varscan2
- FAM234B | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.742); catalogued as rs769080937, COSV52192731; called by muse, mutect2, varscan2
- FAM47B | c.1490A>T p.K497M | Missense Mutation (SNP) | VAF 241/468 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV61452616; called by muse, mutect2, varscan2
- FAT3 | c.7627C>T p.R2543* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as COSV53079774; called by muse, mutect2, varscan2
- GSDMA | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 83/728 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52856544; called by muse, mutect2, varscan2
- H2AP | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV61910785; called by muse, mutect2, varscan2
- HERC1 | c.9953G>A p.R3318Q | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs1422143134, COSV101496840, COSV71246056; called by muse, mutect2
- HTR3E | c.1205G>T p.G402V (on ENST00000415389 / NM_001256613.1; = p.G417V on NM_182589.2) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV58945946; called by muse, mutect2, varscan2
- IL21R | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV61968685; called by muse, varscan2
- IL2RG | c.1082dup p.C362Mfs*7 | Frame Shift Ins (INS) | VAF 18/146 reads (12%) | catalogued as rs745545309; called by mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | catalogued as rs780982673; called by mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 20/192 reads (10%) | catalogued as rs751926247; called by mutect2, varscan2
- KLHL34 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV65278670; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 45/300 reads (15%) | catalogued as rs746133895; called by mutect2, varscan2
- LRP1 | c.4468dup p.E1490Gfs*6 | Frame Shift Ins (INS) | VAF 19/188 reads (10%) | catalogued as rs139915490; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 32/167 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MPO | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776994403, COSV56561566; called by muse, mutect2, varscan2
- MYO1B | c.2329A>G p.K777E | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV58427572; called by muse, mutect2, varscan2
- NAP1L2 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 48/154 reads (31%) | catalogued as COSV65172218; called by muse, varscan2
- OOEP | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as rs1180590771; called by muse, mutect2, varscan2
- OR2L8 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 124/362 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61725724; called by muse, mutect2
- OR51G1 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV58968544; called by muse, mutect2, varscan2
- PCDH11X | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs62621113, COSV53445288, COSV53466454; called by muse, mutect2
- PKHD1 | c.2546C>A p.T849N | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs759247308, COSV61862379; called by muse, mutect2, varscan2
- PPP4R2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55594239; called by muse, mutect2, varscan2
- PTCH1 | c.3425G>A p.G1142E | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59479771; called by muse, mutect2, varscan2
- RBMS3 | c.1186G>T p.V396F (on ENST00000383767 / NM_001003793.3; = p.V380F on NM_014483.3) | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.019); catalogued as COSV56133160; called by muse, mutect2, varscan2
- RGS22 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs766770784, COSV62657743; called by muse, mutect2, varscan2
- RILP | c.700C>A p.R234S | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV53957536; called by muse, mutect2, varscan2
- RYR2 | c.9749G>A p.W3250* | Nonsense Mutation (SNP) | VAF 14/260 reads (5%) | catalogued as COSV63720144; called by muse, mutect2
- SAMSN1 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 183/444 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV53467036, COSV53467999; called by muse, mutect2, varscan2
- SDC2 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV56225978; called by muse, mutect2, varscan2
- SEMA3C | c.1802T>C p.I601T | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV54841858; called by muse, mutect2, varscan2
- SERPINA5 | c.457T>C p.Y153H | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61573599; called by muse, mutect2
- SLC52A3 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs565998859, COSV54076725; ClinVar: uncertain significance; called by muse, varscan2
- SOCS6 | c.166A>G p.I56V | Missense Mutation (SNP) | VAF 141/212 reads (67%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV67546002; called by muse, mutect2, varscan2
- SPATA31A1 | c.3986G>A p.G1329D | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV66533977; called by muse, mutect2, varscan2
- SRPK1 | c.362C>G p.A121G | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60411268; called by muse, mutect2, varscan2
- TCF4 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV61891143; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 53/411 reads (13%) | catalogued as rs782753958; called by mutect2, varscan2
- TRAPPC12 | c.1955G>T p.R652I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60845407; called by muse, mutect2, varscan2
- WDR72 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 130/179 reads (73%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as rs201559909, COSV64742066; called by muse, varscan2
- ASH1L | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ASMT | c.786C>A p.C262* (on ENST00000381229; = p.C290* on NM_004043.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 898/3810 reads (24%) | called by muse, mutect2, varscan2
- DYRK1B | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- ELAPOR1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON4L | c.4569G>T p.E1523D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- LGR5 | c.2589C>G p.D863E | Missense Mutation (SNP) | VAF 56/827 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2
- LRRC3B | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 36/1072 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.698); called by muse, mutect2
- MAP3K14 | c.1948A>G p.K650E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MAP9 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 43/463 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.54); called by muse, mutect2
- MTMR2 | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 106/823 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MYH11 | c.4938G>T p.Q1646H | Missense Mutation (SNP) | VAF 86/1622 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2
- PSMD9 | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- PZP | c.981_982insTGTGTAGGCAACTCTAAAGAGGGACA p.D328Cfs*31 | Frame Shift Ins (INS) | VAF 28/273 reads (10%) | called by mutect2*, pindel
- SSX6P | n.341G>T | Splice Region (SNP) | VAF 26/91 reads (29%) | called by mutect2, varscan2
- THEMIS | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 10/217 reads (5%) | called by muse, mutect2
- VPS13D | c.12934G>A p.V4312I | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ARHGAP45 | c.2811G>A p.T937= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1025670372, COSV53123391; called by muse, mutect2, varscan2
- BCL2L11 | c.177C>T p.S59= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs1394795184; called by mutect2, varscan2
- BCOR | c.4194A>G p.R1398= (on ENST00000378444 / NM_001123385.2; = p.R1364= on NM_017745.6) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV60700934; called by muse, mutect2
- CAMK1G | c.204G>A p.E68= | Silent (SNP) | VAF 62/928 reads (7%) | catalogued as COSV50520326; called by muse, mutect2
- CSNK1A1 | c.138G>A p.K46= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as rs760677105, COSV55793033; called by muse, mutect2, varscan2
- CYP4B1 | c.171T>C p.H57= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV54721477; called by muse, mutect2, varscan2
- DENND6A | c.645T>C p.P215= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV60767696; called by muse, mutect2, varscan2
- DGKK | c.1794T>G p.P598= | Silent (SNP) | VAF 183/547 reads (33%) | catalogued as COSV65706530; called by muse, mutect2, varscan2
- DNAJC4 | c.594C>T p.N198= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV54172314; called by muse, mutect2, varscan2
- DOCK2 | c.4830A>G p.K1610= | Silent (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- DSP | c.1464C>T p.N488= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs768526275, COSV65791390; called by muse, mutect2, varscan2
- FAM83A | c.708C>T p.F236= | Silent (SNP) | VAF 68/208 reads (33%) | catalogued as rs1310137595, COSV52684261; called by muse, mutect2, varscan2
- GNAT3 | c.711C>T p.D237= | Silent (SNP) | VAF 93/347 reads (27%) | catalogued as rs766464364, COSV68067964; called by muse, mutect2, varscan2
- HCRTR2 | c.369A>G p.G123= | Silent (SNP) | VAF 38/1152 reads (3%) | catalogued as COSV63793972; called by muse, mutect2
- HECW1 | c.2352G>A p.P784= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs750828862, COSV67822847; called by muse, mutect2, varscan2
- IFI35 | c.244C>T p.L82= | Silent (SNP) | VAF 33/302 reads (11%) | called by muse, mutect2, varscan2
- MAST2 | c.3486G>A p.G1162= | Silent (SNP) | VAF 8/223 reads (4%) | called by muse, mutect2
- NUMA1 | c.1620A>G p.Q540= | Silent (SNP) | VAF 40/446 reads (9%) | called by muse, mutect2
- PCSK2 | c.1008C>T p.N336= | Silent (SNP) | VAF 88/204 reads (43%) | catalogued as rs762559214, COSV52727055; called by muse, mutect2, varscan2
- PIR | c.66G>A p.A22= | Silent (SNP) | VAF 117/308 reads (38%) | catalogued as rs370522973, COSV62916272; called by muse, mutect2, varscan2
- SYT16 | c.543C>T p.D181= | Silent (SNP) | VAF 551/1262 reads (44%) | catalogued as rs779568303, COSV70855156; called by muse, mutect2, varscan2
- TCEAL1 | c.171C>G p.L57= | Silent (SNP) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- THADA | c.1068G>A p.L356= | Silent (SNP) | VAF 86/269 reads (32%) | catalogued as COSV57676671; called by muse, mutect2, varscan2
- TMEM255A | c.612C>T p.Y204= | Silent (SNP) | VAF 308/746 reads (41%) | catalogued as rs372830851, COSV59028174, COSV59029063; called by muse, mutect2, varscan2
- TRIP12 | c.183G>A p.G61= | Silent (SNP) | VAF 137/542 reads (25%) | catalogued as COSV52259685; called by muse, mutect2, varscan2
- TTK | c.681C>T p.N227= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2, varscan2
